Somatic mutation profile of tumor specimen TCGA-LN-A4A4-01A (aliquot TCGA-LN-A4A4-01A-11D-A27G-09) from TCGA case TCGA-LN-A4A4, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 36.7 years (13,419 days).
Specimen TCGA-LN-A4A4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dab29b4e-db13-4b1e-9a2f-dc4a398dbccd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A4A4-10A (Blood Derived Normal), aliquot TCGA-LN-A4A4-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/534cb959-8b84-4623-ab0e-b542c24827a9

The open-access MAF lists 107 somatic variants for this specimen: 80 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 23, Nonsense Mutation 9, Intron 3, Nonstop Mutation 1, Frame Shift Del 1, RNA 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.782+1G>A p.X261_splice | Splice Site (SNP) | VAF 214/292 reads (73%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AATK | c.3055C>T p.R1019* (on ENST00000326724 / NM_001080395.3; = p.R916* on NM_004920.2) | Nonsense Mutation (SNP) | VAF 24/42 reads (57%) | catalogued as rs778316408; called by muse, mutect2, varscan2
- ACAP2 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1254584476; called by muse, mutect2, varscan2
- ADCY8 | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as rs1235698883; called by muse, mutect2, varscan2
- ARMH4 | c.1102G>T p.G368W | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99958965; called by muse, mutect2, varscan2
- ATP2C1 | c.2353A>G p.I785V | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.074); catalogued as rs907027493; called by muse, mutect2, varscan2
- BBS5 | c.587G>T p.S196I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as rs1193414631; called by muse, mutect2
- CCDC27 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99622797; called by muse, mutect2, varscan2
- CNGB3 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV60696110; called by muse, mutect2, varscan2
- DKK2 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.91); PolyPhen benign (0.189); catalogued as COSV53395034; called by muse, mutect2, varscan2
- ENTPD6 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs771320792; called by muse, mutect2, varscan2
- GPRIN3 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.777); catalogued as rs145667508; called by muse, mutect2, varscan2
- IFI44L | c.1358G>T p.*453Lext*5 | Nonstop Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100654878; called by muse, mutect2, varscan2
- LRRC57 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as rs760414068; called by muse, mutect2, varscan2
- MAP3K1 | c.1969A>G p.T657A | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.214); catalogued as COSV68123226, COSV68123383; called by muse, mutect2, varscan2
- MTBP | c.953A>G p.Y318C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs371337948; called by muse, mutect2, varscan2
- MYO5B | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777038090; called by muse, mutect2, varscan2
- NLRP2 | c.1621G>A p.G541R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs749931307, COSV54754287; called by muse, mutect2, varscan2
- NUP107 | c.2171A>G p.Y724C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.13); catalogued as rs780651405; called by muse, mutect2, varscan2
- OR4K1 | c.446G>A p.W149* | Nonsense Mutation (SNP) | VAF 14/150 reads (9%) | catalogued as rs778170531, COSV53461119, COSV53462369; called by muse, mutect2
- PCDHGA6 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as rs1366674805, COSV53931781; called by muse, mutect2, varscan2
- PRR16 | c.344C>T p.T115M (on ENST00000407149 / NM_001300783.2; = p.T92M on NM_016644.2) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773682575, COSV65399441; called by muse, mutect2, varscan2
- PTPRT | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61974113, COSV61985449, COSV62035189; called by muse, mutect2, varscan2
- PTPRU | c.1828G>A p.V610M | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747973212, COSV60524330; called by muse, mutect2, varscan2
- SI | c.4087C>A p.P1363T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100016718, COSV52292312; called by muse, mutect2, varscan2
- SLC36A2 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as rs766086527, COSV58862540; called by muse, mutect2, varscan2
- SSBP1 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.367); catalogued as COSV54681616; called by muse, mutect2, varscan2
- TOP3B | c.1525G>A p.G509S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762892315; called by muse, mutect2, varscan2
- TSPAN8 | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753825850; called by muse, mutect2, varscan2
- TTN | c.5855A>G p.H1952R (on ENST00000591111; = p.H1906R on NM_003319.4) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | PolyPhen benign (0.122); catalogued as rs572691153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VEGFC | c.302C>G p.S101* | Nonsense Mutation (SNP) | VAF 32/78 reads (41%) | catalogued as COSV54593905; called by muse, mutect2, varscan2
- YBX2 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1247615491, COSV50301842, COSV50302313; called by muse, mutect2, varscan2
- ZNF536 | c.2597C>G p.S866C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV62837074; called by muse, mutect2, varscan2
- ZNF540 | c.311T>C p.I104T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs745556311; called by muse, mutect2, varscan2
- ABCC11 | c.3647C>A p.S1216Y | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ABCC9 | c.2543A>G p.D848G | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ALKBH3 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- ALMS1 | c.11828C>T p.P3943L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- C6orf201 | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT tolerated (0.24); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CACNG5 | c.391G>C p.A131P | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CARD11 | c.1916T>A p.M639K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CASP8 | c.1343A>G p.Y448C (on ENST00000432109 / NM_033355.3; = p.Y465C on NM_001228.4) | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CBL | c.106C>T p.H36Y | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CBLIF | c.412G>C p.A138P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- CCDC171 | c.2330C>G p.S777* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- CENPE | c.457A>G p.I153V | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP350 | c.8539C>T p.Q2847* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- CISD2 | c.280A>T p.T94S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- COL4A6 | c.1457G>A p.G486D | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- CUBN | c.7705G>A p.V2569M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- DOCK5 | c.2006T>C p.L669S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EML3 | c.1929_1930del p.A644* | Frame Shift Del (DEL) | VAF 36/71 reads (51%) | called by pindel, varscan2
- ENOX1 | c.58A>T p.M20L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ENOX1 | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- FCGBP | c.5641C>G p.L1881V | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FER1L5 | c.5546C>T p.P1849L (on ENST00000623019; = p.P1813L on NM_001293083.2) | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GPR4 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- GZF1 | c.454A>T p.S152C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- HSPA1B | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- HTATSF1 | c.2247_2255del p.D751_D753del | In Frame Del (DEL) | VAF 24/79 reads (30%) | called by mutect2, pindel, varscan2
- KIF15 | c.3502G>C p.A1168P | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- KTN1 | c.3853A>G p.K1285E (on ENST00000395314 / NM_001271014.2; = p.K1228E on NM_004986.4) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP6 | c.2374C>T p.R792W | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MAU2 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MIOS | c.2155C>T p.H719Y | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MYNN | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- OR10S1 | c.724A>G p.I242V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.012); called by mutect2, varscan2
- OR8B12 | c.257C>G p.S86* | Nonsense Mutation (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- PCNX1 | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, varscan2
- PPIL2 | c.1028A>T p.E343V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- PROS1 | c.1985G>C p.R662T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- RNF123 | c.1556G>C p.G519A | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.46); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- SBNO2 | c.1169A>C p.H390P | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLC12A1 | c.186T>G p.F62L | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC47A2 | c.806T>A p.L269Q | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SPATA17 | c.625A>G p.K209E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- THSD7A | c.846A>C p.E282D | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VAMP8 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZADH2 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- ACSM1 | c.54C>T p.H18= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs1178409481; called by muse, mutect2, varscan2
- AHDC1 | c.2649G>A p.R883= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs1014075967; called by muse, mutect2, varscan2
- AKT3 | c.792C>A p.S264= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- ANXA2R | c.258G>A p.A86= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs1304459664; called by muse, mutect2, varscan2
- CD300A | c.807G>A p.S269= | Silent (SNP) | VAF 85/115 reads (74%) | catalogued as rs772744436; called by muse, mutect2, varscan2
- CREBBP | c.4926C>T p.V1642= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- DAB2IP | c.2508G>A p.A836= (on ENST00000408936; = p.A808= on NM_032552.3) | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs373684988, COSV99404423; called by muse, varscan2
- EPHA2 | c.1764C>T p.Y588= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as rs148209354; called by muse, mutect2, varscan2
- FUT5 | c.531C>T p.D177= | Silent (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- GINS2 | c.324G>A p.P108= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs541558749, COSV53671038, COSV53675775; called by muse, mutect2
- L3MBTL4 | c.15C>T p.N5= | Silent (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- LGALS8 | c.493C>T p.L165= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs376845621; called by muse, mutect2, varscan2
- LYG1 | c.438A>C p.P146= | Silent (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- NLRC5 | c.4644G>C p.G1548= | Silent (SNP) | VAF 29/128 reads (23%) | called by muse, mutect2, varscan2
- OR10G8 | c.417G>T p.S139= | Silent (SNP) | VAF 36/127 reads (28%) | called by muse, mutect2, varscan2
- PANX3 | c.825C>A p.S275= | Silent (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- PCDH15 | c.1821A>G p.P607= | Silent (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- PRDM9 | c.807G>T p.L269= | Silent (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- PRELP | c.312C>T p.I104= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs776957308; called by muse, mutect2, varscan2
- SH3BGRL2 | c.213T>C p.N71= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as COSV63963897; called by muse, mutect2
- SON | c.4779A>G p.L1593= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs965220193, COSV51663544; called by muse, mutect2, varscan2
- TMEM260 | c.810C>T p.F270= | Silent (SNP) | VAF 22/103 reads (21%) | called by muse, mutect2, varscan2
- ZADH2 | c.471C>T p.G157= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- FAM177A1 | c.-28-13T>C | Intron (SNP) | VAF 49/314 reads (16%) | called by muse, mutect2, varscan2
- FCGR3A | c.-44-49G>A | Intron (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- MIR411 | n.3G>T | RNA (SNP) | VAF 46/128 reads (36%) | called by muse, mutect2, varscan2
- NFYC | c.387+1146G>T | Intron (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
